Surgical pathology report (de-identified scan), TCGA case TCGA-DM-A1HA, project TCGA-COAD (Colon Adenocarcinoma), tissue source site University Of Michigan, specimen TCGA-DM-A1HA-01A (Primary Tumor).

ICD-0-3
Adenocarcinoma, NOS 8140/3
Site: Ascending Colon C18.2 2/10/11 JW

(First Tumor)

Tumor Site:	Ascending Colon		
Date of Cancer Sample Procurement:			
Histology:	Adenocarcinoma		
Description of other histology:			
Grade:	Poorly Differentiated		
Mucinous:	☒ No	☐ Yes	☐ Yes (Focal) ☐ Unknown
Signet Ring Feature:	☒ No	☐ Yes	☐ Yes (Focal) ☐ Unknown
Histologic Heterogeneity:	☐ No	☒ Yes	☐ Unknown
Host Response:	None		
Crohn's like reaction	☒ None	☐ Yes	☐ Unknown
Plasma cell rich stroma	☐ No	☐ Yes	☐ Unknown
Growth Pattern:	☐ Expansile	☐ Invasive	☐ Expansile and Invasive ☒ Unknown
Inflammatory Bowel Disease	☒ No	☐ Yes	☐ Unknown
Angiolymphatic Invasion:	☐ No	☒ Yes	☐ Unknown
Mutator Phenotype:	☐ No	☒ Yes	☐ Unknown
Number of Slides	1		
Garland Necrosis present:	☐ No	☐ Yes	☐ Yes (Focal) ☐ Unknown
TIL Cells / HPF			
Pathologist Comment:	deep edge of tumor not s		

Source: NCI Genomic Data Commons file 992f6ce7-6d69-40af-b917-b18dc3728715 (TCGA-DM-A1HA.9E26E5F5-0FD1-4045-87F6-3C1362F5DF84.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).